Gene-level copy-number profile of specimen HCM-SANG-0274-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-0274-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0274-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3a060599-2dca-41be-9609-7909d15f507b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0274-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/e3828694-b737-4ef5-8572-4f21b6edb8a2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,470; copy number 2: 38,086; copy number 3: 12,481; copy number 4: 5,184; copy number 5: 525; copy number 6: 876; copy number 7: 17; copy number 9: 263; copy number 10: 7.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,934,412–7,938,770, 1 gene (within-gene range 0–1): DEFB108A.
- chr8:8,116,745–8,116,949, 1 gene: SNRPCP17.
- chr8:12,182,096–12,196,280, 2 genes (within-gene range 0–1): FAM86B1, AC145124.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,688 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:2,561,947–4,189,806, 57 genes, copy number 5: AL359852.1, LINC02521, LINC01600, MYLK4, WRNIP1, SERPINB1, SERPINB9P1, MIR4645, SERPINB9, AL133351.2, AL133351.1, SERPINB6, LINC01011, NQO2, NQO2-AS1, HTATSF1P2, AL133351.4, AL133351.3, FAM136BP, SERPINB8P1, AL031963.2, RIPK1, AL031963.3, RNA5SP201, BPHL, AL031963.1, TUBB2A, TUBB2BP1, LINC02525, TUBB2B, PSMG4, SLC22A23, AL445309.1, AL033523.1, AL033523.2, PXDC1, AL391422.4, AL391422.1, AL391422.3, AL391422.2, FAM50B, AL590004.3, AL590004.2, AL590004.1, TDGF1P4, GLRX3P2, AL138831.3, AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1.
- chr6:4,341,756–4,347,162, 1 gene, copy number 5: AL159166.1.
- chr6:4,599,287–4,955,551, 6 genes, copy number 5: AL034376.1, KU-MEL-3, PSMC1P11, CDYL, AL356747.1, CDYL-AS1.
- chr7:32,760,279–56,291,425, 391 genes, copy number 5–9 (within-gene range 2–9) (broad region; genes not listed).
- chr7:66,376,044–66,995,587, 32 genes, copy number 5–7 (within-gene range 4–7): LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2, RABGEF1, AC027644.3, AC027644.2, GTF2IRD1P1, AC027644.1, GTF2IP23, RNU6-1254P, LINC02604, AC073335.1, Metazoa_SRP, TMEM248, RN7SL43P, SBDS.
- chr7:71,779,491–72,447,151, 4 genes, copy number 5: CALN1, RNA5SP232, AC005011.1, ABCF2P2.
- chr7:150,368,790–150,410,597, 2 genes, copy number 5 (within-gene range 4–5): ZNF775, AC073111.2.
- chr7:150,400,702–151,277,896, 45 genes, copy number 5: AC073111.3, LINC00996, GIMAP8, AC073111.1, STRADBP1, GIMAP7, ALDH7A1P3, GIMAP4, AC069304.3, AC069304.1, GIMAP6, AC069304.2, GIMAP2, GIMAP1, GIMAP1-GIMAP5, GIMAP5, GIMAP3P, BET1P1, TMEM176B, TMEM176A, AOC1, KCNH2, NOS3, ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1.
- chr8:36,784,324–37,983,373, 31 genes, copy number 5: KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48.
- chr8:38,062,881–40,897,833, 61 genes, copy number 5 (broad region; genes not listed).
- chr8:41,032,892–42,541,926, 39 genes, copy number 5 (within-gene range 4–5): RNU6-356P, SFRP1, MIR548AO, RPS29P2, AC104393.1, RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2.
- chr8:42,537,529–49,554,414, 105 genes, copy number 5 (broad region; genes not listed).
- chr8:49,906,863–53,251,637, 31 genes, copy number 5: AC023762.1, SNTG1, AC090539.1, AC090539.2, CYCSP22, AC087272.1, AC090919.1, AC012413.1, PXDNL, BRIX1P1, BTF3P1, AC090186.1, PCMTD1, AC103769.1, AC064807.1, AC064807.4, AC064807.2, AC064807.3, ST18, AC021915.2, AC021915.1, AC103831.1, RPL34P17, ALKAL1, RB1CC1, AC113139.1, NPBWR1, AC009800.1, AC009646.1, AC009646.2, OPRK1.
- chr8:85,744,543–85,828,467, 7 genes, copy number 10: REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P.
- chr20:26,103,416–64,327,972, 876 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,400. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
